Gene-level copy-number profile of tumor specimen TCGA-CD-A4MH-01A from TCGA case TCGA-CD-A4MH, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 86.7 years (31,683 days).
Specimen TCGA-CD-A4MH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.56596014-c368-4b2d-bd4b-514d84d5df7a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CD-A4MH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3d8f6e12-e933-46b9-9ba6-7684956b604a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 338; copy number 2: 29,384; copy number 3: 15,406; copy number 4: 7,712; copy number 5: 4,319; copy number 6: 931; copy number 7: 1,165; copy number 8: 549; copy number 9: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CD-A4MH-01A-11D-A253-01): tumor purity 0.54, ploidy 2.8, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,973 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:22,863,159–24,673,281, 62 genes, copy number 5 (broad region; genes not listed).
- chr1:61,742,477–64,181,498, 58 genes, copy number 5 (within-gene range 2–5): PATJ, RNU6-414P, RNU6-1177P, LAMTOR5P1, RN7SL180P, MIR3116-1, MIR3116-2, PIGPP2, RPS15AP7, L1TD1, AL162739.1, Y_RNA, KANK4, RNU6-371P, USP1, DOCK7, AL451044.1, ANGPTL3, AL138847.2, AL138847.1, AC103923.1, ATG4C, AC099794.1, AC099794.2, LINC01739, AL162400.3, AL162400.1, AL162400.2, AC096543.1, LINC00466, RNA5SP49, AC096543.2, RPSAP65, FOXD3-AS1, FOXD3, MIR6068, Y_RNA, AL049636.1, ALG6, ITGB3BP, BX004807.1, EFCAB7, RN7SL488P, RNU7-123P, DLEU2L, AL109925.3, AL109925.6, AL109925.4, AL109925.2, AL109925.5, AL109925.1, PGM1, RN7SL130P, ROR1, AL161742.1, CFL1P3, RNU6-809P, Y_RNA.
- chr1:152,032,506–152,196,699, 8 genes, copy number 9: S100A11, SPTLC1P4, AL591893.1, TCHHL1, TCHH, AL589986.1, PUDPP2, RPTN.
- chr1:152,205,858–152,207,057, 1 gene, copy number 9: AL589986.2.
- chr1:234,593,275–235,161,283, 23 genes, copy number 6: U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, AL160408.6, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1, AL732292.2, TOMM20, SNORA14B, RBM34.
- chr1:235,190,034–235,190,116, 1 gene, copy number 6: MIR4753.
- chr2:74,918,148–75,199,520, 7 genes, copy number 5 (within-gene range 3–5): LINC01291, AC104135.1, LINC01293, POLE4, TACR1, MIR5000, AC007681.1.
- chr5:58,198–45,895,970, 710 genes, copy number 7 (broad region; genes not listed).
- chr5:176,810,519–177,081,189, 5 genes, copy number 6 (within-gene range 2–6): UNC5A, HK3, UIMC1, ZNF346, ZNF346-IT1.
- chr6:30,414,715–31,203,968, 60 genes, copy number 5: MICC, AL662873.1, TMPOP1, SUCLA2P1, RANP1, HLA-E, LINC02569, GNL1, PRR3, ABCF1, MIR877, PPP1R10, MRPS18B, ATAT1, PTMAP1, C6orf136, DHX16, PPP1R18, NRM, RPL7P4, MDC1, MDC1-AS1, TUBB, AL662797.1, FLOT1, Y_RNA, IER3-AS1, IER3, HCG20, RN7SL353P, LINC00243, LINC02570, RN7SKP186, DDR1-DT, DDR1, MIR4640, GTF2H4, AL669830.1, VARS2, SFTA2, Y_RNA, MUCL3, HCG21, NAPGP2, MUC21, MUC22, HCG22, RNU6-1133P, C6orf15, PSORS1C1, CDSN, PSORS1C2, POLR2LP1, CCHCR1, TCF19, POU5F1, PSORS1C3, AL662844.4, HCG27, AL662844.3.
- chr6:168,194,358–168,375,355, 9 genes, copy number 8 (within-gene range 3–8): AL611929.1, AL606970.5, AL606970.4, AL606970.2, AL606970.3, CTAGE13P, DACT2, AL606970.1, AL138918.1.
- chr7:74,453,790–74,602,605, 1 gene, copy number 6 (within-gene range 4–6): GTF2IRD1.
- chr7:74,606,913–77,462,139, 100 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr9:14,475–7,961,224, 139 genes, copy number 5 (broad region; genes not listed).
- chr9:8,700,595–9,091,245, 6 genes, copy number 5: AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3.
- chr9:16,203,935–27,610,745, 160 genes, copy number 5 (broad region; genes not listed).
- chr10:31,033,089–33,336,262, 43 genes, copy number 6 (within-gene range 3–6): AL359546.1, LINC02664, ZEB1-AS1, RNA5SP309, ZEB1, SPTLC1P1, AL117340.1, AL161935.1, AL161935.3, AL161935.2, MACORIS, Y_RNA, ARHGAP12, HMGB1P7, RPL34P19, RN7SL825P, KIF5B, Y_RNA, RPS4XP11, AL161932.2, AL161932.1, RNU7-22P, PPIAP31, RPS24P13, AL158834.2, EPC1, AL158834.1, AL391839.2, AL391839.1, RNU6-1244P, AL391839.3, CCDC7, C1DP1, ITGB1, AK3P5, ITGB1-DT, MTND4LP11, RN7SL847P, AL365203.1, RPL7AP53, IATPR, NRP1, AL121748.1.
- chr11:167,784–9,138,114, 464 genes, copy number 5 (broad region; genes not listed).
- chr11:9,754,770–135,075,908, 2,874 genes, copy number 5 (broad region; genes not listed).
- chr16:84,974,175–85,094,230, 2 genes, copy number 6 (within-gene range 2–6): ZDHHC7, KIAA0513.
- chr17:27,057,399–30,542,416, 186 genes, copy number 5 (broad region; genes not listed).
- chr17:42,968,088–43,787,620, 51 genes, copy number 5 (within-gene range 2–5): PTGES3L, RUNDC1, RPL27, IFI35, VAT1, RND2, BRCA1, RPL21P4, NBR2, AC135721.2, AC135721.1, AC060780.1, BRCA1P1, AC060780.2, NBR1, TMEM106A, CCDC200, RNU2-1, U2, U2, U2, U2, U2, U2, U2, U2, U2, U2, U2, U2, LINC00910, AC109326.1, RNU2-4P, RNU6-1137P, ARL4D, RNU6-470P, MIR2117HG, MIR2117, RNU6-406P, RNU6-971P, AC087650.1, DHX8, ETV4, Metazoa_SRP, MEOX1, LINC02594, WHSC1L2P, SOST, DUSP3, CFAP97D1, AC003098.1.
- chr17:49,598,884–52,160,017, 90 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr19:27,638,483–39,846,379, 455 genes, copy number 7 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 338. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
